Somatic mutation profile of tumor specimen TCGA-EJ-7318-01B (aliquot TCGA-EJ-7318-01B-11D-A32B-08) from TCGA case TCGA-EJ-7318, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.2 years (18,686 days).
Specimen TCGA-EJ-7318-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0370f970-42a8-4aa3-bd4c-441574a354d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7318-10A (Blood Derived Normal), aliquot TCGA-EJ-7318-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683308c0-1b1b-4f9f-a5f0-7ade064689b1

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4210C>A p.P1404T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166391; called by muse, mutect2, varscan2
- ARRDC5 | c.1006G>A p.V336M (on ENST00000381781; = p.V322M on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs370201794; called by muse, mutect2, varscan2
- CIB1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775605318, COSV100153429; called by muse, mutect2, varscan2
- COL5A3 | c.2350A>T p.K784* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99319708; called by muse, mutect2, varscan2
- CRACD | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51724856, COSV99949937; called by muse, mutect2
- DCLRE1B | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99871106; called by muse, mutect2, varscan2
- EPHA3 | c.2074+1G>T p.X692_splice | Splice Site (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100348290; called by muse, mutect2, varscan2
- FGFBP2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs768845048, COSV52588080, COSV99469535; called by muse, mutect2, varscan2
- GIGYF1 | c.1999A>G p.I667V | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs553089567, COSV99309940; called by muse, mutect2
- GRIA1 | c.2324A>T p.K775I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99602113; called by muse, mutect2
- ITGA8 | c.2822G>C p.G941A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100959246, COSV100959646; called by muse, mutect2, varscan2
- KAT6B | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768962; called by muse, mutect2
- LRRTM1 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99703068; called by muse, mutect2, varscan2
- MECR | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV99747383; called by muse, mutect2
- NUFIP1 | c.1007T>G p.I336R | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100998057; called by muse, mutect2, varscan2
- NUP188 | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs896425897, COSV100999702; called by muse, mutect2, varscan2
- OR5D18 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs577643505, COSV61738236, COSV61738342; called by muse, mutect2, varscan2
- PCDH19 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1210258504, COSV99720697; called by muse, mutect2, varscan2
- PCDHB8 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as rs782085896, COSV50754200, COSV50809082; called by muse, mutect2
- SLC8A1 | c.2915del p.G972Afs*? | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as COSV60486389; called by mutect2, pindel, varscan2
- SOCS4 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100216331; called by muse, mutect2, varscan2
- SPTA1 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs550425124, COSV63750216; called by muse, mutect2, varscan2
- ICAM4 | c.567C>T p.A189= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV99321115; called by muse, mutect2
- LRRC10 | c.678C>T p.N226= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs367700049; called by muse, mutect2, varscan2
- PPP2R3A | c.1992C>T p.I664= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1559863464, COSV99388074; called by muse, mutect2, varscan2
- RYR1 | c.14700C>T p.D4900= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs759063883, COSV62100186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.2034T>C p.H678= | Silent (SNP) | VAF 115/311 reads (37%) | catalogued as rs765457584, COSV100764516; called by muse, mutect2, varscan2
